Somatic mutation profile of tumor specimen TCGA-93-7348-01A (aliquot TCGA-93-7348-01A-21D-2036-08) from TCGA case TCGA-93-7348, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.2 years (27,456 days).
Specimen TCGA-93-7348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edbbf735-d52b-42e2-9da3-26e69d3348f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-7348-10A (Blood Derived Normal), aliquot TCGA-93-7348-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b24cf492-595c-47b8-a62c-3d40ec30f2da

The open-access MAF lists 113 somatic variants for this specimen: 89 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 21, Nonsense Mutation 5, Intron 3, Splice Site 3, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+1G>A p.X1010_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); catalogued as COSV59256499, COSV59256681, COSV59259384, COSV59260405; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RYR1 | c.6274+1G>A p.X2092_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as rs1226228092, COSV62098396; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACSM5 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as COSV59371704, COSV59371725; called by muse, mutect2, varscan2
- ADNP2 | c.2544C>G p.H848Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV51536334, COSV51538988; called by muse, mutect2, varscan2
- AGBL2 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs374430629; called by muse, mutect2, varscan2
- AL121899.2 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV67350220, COSV67350807; called by muse, mutect2, varscan2
- ALX4 | c.781T>C p.W261R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61326653; called by muse, mutect2, varscan2
- ATP2A2 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM011281, COSV57875459; called by muse, mutect2, varscan2
- BMPER | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV51819440, COSV51823831; called by muse, mutect2, varscan2
- C8orf34 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV61381026; called by muse, mutect2, varscan2
- CAMK2B | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51660514, COSV51660881; called by muse, mutect2, varscan2
- CCDC88A | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV55062305; called by muse, mutect2, varscan2
- CCSER1 | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.206); catalogued as COSV61433544; called by muse, mutect2, varscan2
- CNST | c.983A>G p.H328R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1004981561, COSV63621837; called by muse, varscan2
- CPB2 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51674426; called by muse, mutect2
- CYTH4 | c.838T>A p.W280R | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958202; called by muse, mutect2
- DACH2 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); catalogued as COSV100913982; called by muse, mutect2, varscan2
- DEFA4 | c.294A>T p.*98Yext*30 | Nonstop Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV52404465, COSV52404817; called by muse, mutect2, varscan2
- DGKK | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV101053222; called by muse, mutect2
- DIDO1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs770549757, COSV56623373, COSV56627673; called by muse, mutect2, varscan2
- DLX4 | c.554G>A p.G185E (on ENST00000240306 / NM_138281.3; = p.G113E on NM_001934.3) | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53591731; called by muse, mutect2, varscan2
- DNAJC3 | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV65131575; called by muse, mutect2, varscan2
- EYS | c.581G>T p.W194L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.373); catalogued as COSV60986518; called by muse, mutect2, varscan2
- FAM171A1 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV65314419, COSV65316526; called by muse, mutect2, varscan2
- FAM9A | c.975T>A p.S325R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66813277; called by muse, mutect2, varscan2
- FERMT3 | c.1723A>C p.N575H (on ENST00000279227 / NM_178443.3; = p.N571H on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.501); catalogued as COSV54173676; called by muse, mutect2, varscan2
- FLG | c.4488C>G p.S1496R | Missense Mutation (SNP) | VAF 239/751 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as rs374409476, COSV100912146, COSV64242400; called by muse, mutect2, varscan2
- GABRQ | c.519C>A p.Y173* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV64782190; called by muse, mutect2
- GDE1 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1436465969, COSV54904522; called by muse, mutect2, varscan2
- HHIPL2 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58565406; called by muse, mutect2, varscan2
- HNF4A | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57383363; called by muse, mutect2, varscan2
- HOXB1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV53317333; called by muse, mutect2, varscan2
- IFT88 | c.1384G>T p.A462S (on ENST00000319980 / NM_001318493.2; = p.A453S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV60673813; called by muse, mutect2, varscan2
- ITGA5 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV53217952; called by muse, mutect2, varscan2
- ITPR2 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV67269785; called by muse, mutect2, varscan2
- KCNH8 | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as COSV60464527; called by muse, mutect2, varscan2
- KRT6B | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV52883936; called by muse, mutect2
- M1AP | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51844738; called by muse, mutect2
- MAGEA12 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); catalogued as COSV63294869; called by muse, mutect2
- MAGEC2 | c.971C>A p.T324N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV55999518; called by muse, mutect2, varscan2
- MUC4 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.494); catalogued as COSV62152286; called by muse, mutect2, varscan2
- MYH3 | c.4403T>C p.L1468P | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56865415; called by muse, mutect2
- MYLK | c.5488T>A p.C1830S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60610880; called by muse, mutect2
- NELL1 | c.2039T>C p.L680P | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs1274325805, COSV54268577; called by muse, mutect2, varscan2
- NEURL1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs746290099, COSV63509947; called by muse, mutect2, varscan2
- NOL4 | c.143C>A p.T48K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV52343715, COSV52347756; called by muse, mutect2, varscan2
- NTNG1 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53972634; called by muse, mutect2, varscan2
- NYAP2 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56005844; called by muse, mutect2, varscan2
- OR2F1 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV67331443; called by muse, mutect2, varscan2
- OR56B1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV57722697, COSV57723201; called by muse, mutect2, varscan2
- PAK5 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62021854, COSV62028388; called by muse, mutect2
- PAPSS1 | c.878T>A p.F293Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54489325; called by muse, mutect2, varscan2
- PCDHA11 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.223); catalogued as rs782072957, COSV56498697; called by muse, mutect2
- POTEF | c.2525T>A p.L842Q | Missense Mutation (SNP) | VAF 44/442 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62541410; called by muse, varscan2
- PREX2 | c.3125T>C p.M1042T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55772316; called by muse, mutect2, varscan2
- PSG11 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV60455354; called by muse, mutect2
- QPCT | c.548C>G p.T183S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.058); catalogued as rs151306583; called by muse, mutect2, varscan2
- RAD51AP2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV67588156; called by muse, mutect2, varscan2
- RAG1 | c.1574C>A p.P525H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55025504, COSV55029071; called by muse, mutect2, varscan2
- REV1 | c.3301A>C p.T1101P | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51485492; called by muse, mutect2, varscan2
- SALL4 | c.1967C>T p.T656M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1445986638, COSV53852545; called by muse, mutect2
- SAMD4B | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV55394244; called by muse, mutect2
- SLC45A2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV56872078; called by muse, mutect2, varscan2
- SPATA7 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV50417383; called by muse, mutect2
- SPRY2 | c.793_794insAAA p.C265delins* | Nonsense Mutation (INS) | VAF 10/65 reads (15%) | catalogued as COSV101001752; called by mutect2, pindel, varscan2
- SRPX | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV59438897; called by muse, mutect2, varscan2
- TAS2R38 | c.726C>A p.H242Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV101516496, COSV71885496; called by muse, mutect2, varscan2
- TGIF2LX | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV52214100; called by muse, mutect2, varscan2
- TH | c.568G>T p.A190S (on ENST00000381178 / NM_199292.3; = p.A159S on NM_000360.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.035); catalogued as COSV60767027, COSV60768752; called by muse, mutect2
- TRAPPC13 | c.1015C>A p.L339M | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51557945; called by muse, mutect2, varscan2
- TRIB1 | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV61334857; called by muse, mutect2, varscan2
- TRPC5 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV53291320; called by muse, mutect2
- TRPM8 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV61222121; called by muse, mutect2
- UBE4B | c.2276T>G p.F759C (on ENST00000343090 / NM_001105562.3; = p.F630C on NM_006048.5) | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53533179; called by muse, mutect2
- UGT1A1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1247729976, COSV59389360; called by muse, mutect2
- UNC5A | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV56168593; called by muse, mutect2, varscan2
- UNC5A | c.1727G>A p.G576D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52840479; called by muse, mutect2, varscan2
- USH2A | c.5566G>C p.E1856Q | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.526); catalogued as COSV56374544; called by muse, mutect2
- VPS33B | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV60980268; called by muse, mutect2
- YARS2 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as COSV61401928; called by muse, mutect2
- ZFPM2 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV65873858; called by muse, mutect2
- ZFYVE26 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs1168269050, COSV61328912; called by muse, mutect2, varscan2
- ZNF511 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.246); catalogued as COSV62920025; called by muse, mutect2, varscan2
- ZNF813 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67176634; called by muse, mutect2
- ZNF831 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250498082, COSV64040680; called by muse, mutect2
- FCGBP | c.2829+1G>T p.X943_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- IGKV3-7 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TRBV24-1 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ASMT | c.393C>T p.Y131= | Silent (SNP) | VAF 15/193 reads (8%) | catalogued as COSV67109897; called by muse, mutect2
- CCNY | c.660C>T p.I220= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs1420625143, COSV55185433; called by muse, mutect2
- CFAP58 | c.423A>T p.S141= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV57212278; called by muse, mutect2
- CLEC11A | c.852C>T p.S284= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1240401720, COSV51574129; called by muse, mutect2, varscan2
- CLYBL | c.381G>T p.R127= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59222142; called by muse, mutect2, varscan2
- COL15A1 | c.1920T>A p.V640= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV66645398; called by muse, mutect2, varscan2
- ERCC6L | c.3672T>C p.V1224= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV57820786; called by muse, mutect2
- FAT3 | c.12342G>A p.V4114= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53116249; called by muse, mutect2
- ITGA10 | c.1677G>A p.L559= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as COSV65197524; called by muse, mutect2
- LIMS1 | c.609C>T p.R203= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs111779374, COSV57540379; called by muse, mutect2, varscan2
- MAGEA10 | c.372A>G p.P124= | Silent (SNP) | VAF 18/171 reads (11%) | catalogued as COSV54884081; called by muse, mutect2, varscan2
- MAMLD1 | c.360G>T p.A120= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV53375225; called by muse, mutect2, varscan2
- MTUS2 | c.1248A>T p.P416= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV70916984; called by muse, mutect2, varscan2
- OR1K1 | c.594G>A p.L198= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV52956582; called by muse, mutect2, varscan2
- OR4A5 | c.123G>T p.L41= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs759199604, COSV60522692; called by muse, mutect2, varscan2
- OR5T2 | c.714C>A p.L238= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV57589349; called by muse, mutect2, varscan2
- PDE1C | c.1557G>A p.E519= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV58514906; called by muse, mutect2
- PIGB | c.366A>T p.A122= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51241915; called by muse, mutect2
- TMEM179B | c.24C>T p.R8= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1457779731, COSV53668677; called by muse, mutect2
- USP35 | c.1446C>T p.T482= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs763234129, COSV71572856; called by muse, mutect2, varscan2
- WRN | c.984A>T p.V328= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV53300645; called by mutect2, varscan2
- ABCA1 | c.720+2520C>T | Intron (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101037708; called by muse, mutect2, varscan2
- MACF1 | c.15832-10115C>G | Intron (SNP) | VAF 9/159 reads (6%) | catalogued as COSV57122943, COSV99240906; called by muse, mutect2
- NFASC | c.2470+2079G>T | Intron (SNP) | VAF 6/87 reads (7%) | catalogued as COSV100365823; called by muse, mutect2
